Somatic mutation profile of tumor specimen C3N-01830-02 (aliquot CPT0097300009) from CPTAC case C3N-01830, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 73.4 years (26,812 days).
Specimen C3N-01830-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3545b147-93dc-44af-831d-c0613c837546.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01830-31 (Blood Derived Normal), aliquot CPT0097330002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/708f88a8-83b6-4bff-8ca7-f55715318aa2

The open-access MAF lists 74 somatic variants for this specimen: 51 protein-altering or splice-affecting, 17 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 17, Nonsense Mutation 5, 3'UTR 3, Intron 3, Frame Shift Del 2, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCND1 | c.857C>T p.T286I | Missense Mutation (SNP) | VAF 17/49 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57119829, COSV99919330; called by mutect2, varscan2
- CTNNB1 | c.100G>A p.G34R | Missense Mutation (SNP) | VAF 118/316 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913399, COSV62687911, COSV62687931, COSV62721471; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- INPPL1 | c.2071C>T p.R691W | Missense Mutation (SNP) | VAF 82/255 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs878853123, CM130291, COSV53356081; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1745+2dup p.X582_splice (on ENST00000521381 / NM_181523.3; = p.X312_splice on NM_181504.4) | Splice Site (INS) | VAF 43/137 reads (31%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 247/344 reads (72%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.1273C>T p.Q425* | Nonsense Mutation (SNP) | VAF 84/265 reads (32%) | catalogued as COSV61383185; called by muse, mutect2, varscan2
- BMP2 | c.371C>T p.T124M | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs150153389; called by muse, mutect2, varscan2
- CNTN4 | c.2762G>A p.W921* | Nonsense Mutation (SNP) | VAF 134/386 reads (35%) | catalogued as COSV100638862; called by muse, mutect2, varscan2
- CTNNA3 | c.1610C>T p.A537V | Missense Mutation (SNP) | VAF 21/366 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs769674937, COSV65597724; ClinVar: uncertain significance; called by muse, mutect2
- DIDO1 | c.2227C>T p.R743C | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56615797; called by muse, varscan2
- DPF2 | c.1045G>T p.D349Y | Missense Mutation (SNP) | VAF 61/214 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52890310; called by muse, mutect2, varscan2
- EFTUD2 | c.2869A>G p.M957V | Missense Mutation (SNP) | VAF 67/211 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.643); catalogued as COSV53655056; called by muse, mutect2, varscan2
- FAM120A | c.1772C>T p.A591V | Missense Mutation (SNP) | VAF 55/162 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.039); catalogued as COSV99464401; called by muse, mutect2, varscan2
- GALNT16 | c.1408G>A p.A470T | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs759818381, COSV100546340, COSV61885681; called by muse, varscan2
- HECTD3 | c.1690G>A p.V564M | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.115); catalogued as rs780936179, COSV64670590; called by muse, mutect2, varscan2
- HS3ST3A1 | c.914G>A p.R305H | Missense Mutation (SNP) | VAF 48/207 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as COSV99404105; called by muse, mutect2, varscan2
- IL17REL | c.301G>A p.G101R | Missense Mutation (SNP) | VAF 50/146 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.705); catalogued as rs774797196; called by muse, mutect2, varscan2
- KPRP | c.1160G>A p.R387H | Missense Mutation (SNP) | VAF 72/197 reads (37%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.027); catalogued as rs1454934158, COSV64220960; called by muse, mutect2, varscan2
- LRRK2 | c.7327C>T p.R2443* | Nonsense Mutation (SNP) | VAF 76/215 reads (35%) | catalogued as rs768396410, COSV54161126; called by muse, mutect2, varscan2
- MRPS18B | c.217G>A p.V73I | Missense Mutation (SNP) | VAF 76/216 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs144768627; called by muse, mutect2, varscan2
- NSD1 | c.5074C>A p.H1692N | Missense Mutation (SNP) | VAF 114/329 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61783886; called by muse, mutect2, varscan2
- P4HA2 | c.80T>C p.I27T | Missense Mutation (SNP) | VAF 43/131 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as rs1412889284; called by muse, mutect2, varscan2
- PCNX3 | c.5957C>T p.S1986L | Missense Mutation (SNP) | VAF 60/190 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs898532295; called by muse, mutect2, varscan2
- PI4KA | c.2638G>A p.A880T | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.079); catalogued as rs373717608; called by muse, mutect2, varscan2
- PITPNM2 | c.40G>A p.V14M | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs140068156, COSV54907423; called by muse, mutect2, varscan2
- PTPRQ | c.4856C>T p.S1619L (on ENST00000616559; = p.S1577L on NM_001145026.2) | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.292); catalogued as rs761152331, COSV57033527; called by muse, mutect2, varscan2
- SERPINE1 | c.880C>T p.R294C | Missense Mutation (SNP) | VAF 144/384 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1397842827, COSV56171861; called by muse, mutect2, varscan2
- SLC22A1 | c.1582G>A p.A528T | Missense Mutation (SNP) | VAF 41/146 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.686); catalogued as rs1283229958; called by muse, mutect2, varscan2
- SORBS1 | c.2900C>G p.P967R | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.48); catalogued as COSV53355699; called by muse, mutect2, varscan2
- STT3B | c.1856C>T p.T619M | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1342556595; called by muse, mutect2, varscan2
- TRPM2 | c.2902C>T p.R968* | Nonsense Mutation (SNP) | VAF 65/175 reads (37%) | catalogued as rs143942852; called by muse, mutect2, varscan2
- WDR88 | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs1238290762, COSV50121340; called by muse, mutect2, varscan2
- ACAP3 | c.995dup p.E333Rfs*14 | Frame Shift Ins (INS) | VAF 53/182 reads (29%) | called by mutect2, pindel, varscan2
- ADGRL2 | c.3073C>G p.P1025A (on ENST00000370717 / NM_001366005.1; = p.P1012A on NM_012302.4) | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ATP6V0A1 | c.397del p.R133Afs*34 | Frame Shift Del (DEL) | VAF 57/210 reads (27%) | called by mutect2, pindel, varscan2
- C17orf97 | c.686C>T p.P229L | Missense Mutation (SNP) | VAF 99/364 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- COL22A1 | c.3566G>T p.G1189V | Missense Mutation (SNP) | VAF 52/171 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- DNAJB1 | c.409G>A p.G137S | Missense Mutation (SNP) | VAF 47/132 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- ELL | c.949T>A p.S317T | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- EPHA10 | c.1037A>G p.Y346C | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- FOXH1 | c.413G>T p.G138V | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KCNA5 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.53); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- KLHL13 | c.32G>A p.W11* | Nonsense Mutation (SNP) | VAF 21/79 reads (27%) | called by muse, mutect2, varscan2
- NDUFA9 | c.500T>C p.V167A | Missense Mutation (SNP) | VAF 54/163 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); called by muse, mutect2, varscan2
- NMUR1 | c.610C>A p.Q204K | Missense Mutation (SNP) | VAF 67/166 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- NOX1 | c.711G>T p.E237D | Missense Mutation (SNP) | VAF 49/179 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NSD1 | c.8058del p.S2687Vfs*74 | Frame Shift Del (DEL) | VAF 62/175 reads (35%) | called by mutect2, pindel, varscan2
- PGLYRP3 | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- PTBP2 | c.1540A>C p.I514L (on ENST00000426398 / NM_001300986.2; = p.I505L on NM_021190.4) | Missense Mutation (SNP) | VAF 7/136 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.894); called by muse, mutect2
- RPL13A | c.568G>T p.D190Y | Missense Mutation (SNP) | VAF 46/155 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- TDRD15 | c.5277G>T p.M1759I | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- ADGRA1 | c.939G>A p.S313= | Silent (SNP) | VAF 76/216 reads (35%) | catalogued as rs556130958; called by muse, mutect2, varscan2
- BTBD11 | c.2307C>T p.A769= (on ENST00000280758 / NM_001018072.2; = p.A306= on NM_001017523.2) | Silent (SNP) | VAF 76/230 reads (33%) | catalogued as rs375379802, COSV55025341; called by muse, mutect2, varscan2
- CCDC166 | c.1293G>A p.A431= | Silent (SNP) | VAF 20/51 reads (39%) | called by muse, mutect2, varscan2
- CNST | c.672C>G p.L224= | Silent (SNP) | VAF 45/141 reads (32%) | catalogued as rs377066455, COSV100829777, COSV100829901; called by muse, mutect2, varscan2
- FGD1 | c.207C>T p.G69= | Silent (SNP) | VAF 71/208 reads (34%) | catalogued as rs886043842; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLG2 | c.5325C>T p.G1775= | Silent (SNP) | VAF 80/197 reads (41%) | catalogued as rs759778011, COSV66170893; called by muse, mutect2, varscan2
- KHDC3L | c.24G>A p.P8= | Silent (SNP) | VAF 58/163 reads (36%) | catalogued as rs148734762; called by muse, mutect2, varscan2
- MOBP | c.480G>A p.P160= (on ENST00000420739; = p.P184= on NM_001278322.2) | Silent (SNP) | VAF 32/96 reads (33%) | called by muse, mutect2, varscan2
- MYOM1 | c.3279G>A p.A1093= | Silent (SNP) | VAF 57/158 reads (36%) | catalogued as rs780325785; called by muse, mutect2, varscan2
- NAA11 | c.132C>T p.I44= | Silent (SNP) | VAF 44/153 reads (29%) | catalogued as COSV54515200; called by muse, mutect2, varscan2
- PCDHA2 | c.183G>A p.P61= | Silent (SNP) | VAF 119/407 reads (29%) | catalogued as COSV65367467; called by muse, mutect2, varscan2
- PCDHB10 | c.825G>A p.A275= | Silent (SNP) | VAF 83/245 reads (34%) | catalogued as rs530052617; called by muse, mutect2, varscan2
- SOX6 | c.912C>G p.P304= | Silent (SNP) | VAF 92/294 reads (31%) | catalogued as rs772358464, COSV100323421, COSV57035743; called by muse, mutect2, varscan2
- STOML2 | c.552C>T p.P184= | Silent (SNP) | VAF 93/217 reads (43%) | catalogued as rs141748962; called by muse, mutect2, varscan2
- TNFRSF9 | c.579G>A p.A193= | Silent (SNP) | VAF 48/134 reads (36%) | catalogued as rs192265662; called by muse, mutect2, varscan2
- TRPS1 | c.765G>A p.R255= (on ENST00000220888 / NM_001330599.2; = p.R268= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/129 reads (5%) | called by muse, mutect2
- VMAC | c.60C>T p.H20= | Silent (SNP) | VAF 45/138 reads (33%) | catalogued as rs1215802071; called by muse, mutect2, varscan2
- C12orf65 | c.282+17C>T | Intron (SNP) | VAF 29/83 reads (35%) | catalogued as rs1197939863; called by muse, mutect2, varscan2
- CHST6 | c.*3G>A | 3'UTR (SNP) | VAF 76/221 reads (34%) | catalogued as rs1264889097, COSV60000996; called by muse, mutect2, varscan2
- CSH1 | c.456+12G>A | Intron (SNP) | VAF 151/426 reads (35%) | catalogued as rs750903185, COSV100298177, COSV100298201, COSV60242731; called by muse, mutect2, varscan2
- GNRHR | c.*44T>A | 3'UTR (SNP) | VAF 42/107 reads (39%) | called by muse, mutect2, varscan2
- SF1 | c.*356C>T | 3'UTR (SNP) | VAF 38/119 reads (32%) | catalogued as COSV57115161; called by muse, mutect2, varscan2
- SYT16 | c.994-1486G>T | Intron (SNP) | VAF 13/33 reads (39%) | called by muse, mutect2, varscan2
